Somatic mutation profile of tumor specimen TCGA-E7-A677-01A (aliquot TCGA-E7-A677-01A-11D-A30E-08) from TCGA case TCGA-E7-A677, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 81.1 years (29,613 days).
Specimen TCGA-E7-A677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 725f17dc-3b82-4067-99e3-e15236555c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A677-10A (Blood Derived Normal), aliquot TCGA-E7-A677-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/929650d9-c278-4665-bf19-ed224664e165

The open-access MAF lists 262 somatic variants for this specimen: 196 protein-altering or splice-affecting, 58 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 58, Frame Shift Del 7, Nonsense Mutation 7, In Frame Del 5, Intron 3, Splice Region 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 34/41 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 74/145 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1970T>C p.L657P | Missense Mutation (SNP) | VAF 60/73 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52636578; called by muse, mutect2, varscan2
- ACACB | c.5543C>T p.A1848V | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58130155; called by muse, mutect2
- ACER3 | c.453G>C p.M151I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV53597628; called by muse, mutect2, varscan2
- ACTG1 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59509875; called by muse, mutect2
- ADAM22 | c.98_110del p.L33* | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as COSV55971877; called by mutect2, pindel, varscan2
- ADAMTS7 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV101183031, COSV66306280; called by muse, mutect2, varscan2
- ADD1 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV53266920; called by muse, mutect2, varscan2
- ADH4 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV55500408; called by muse, mutect2, varscan2
- AGRN | c.3003dup p.G1002Rfs*58 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs763573703; called by mutect2, varscan2
- AKT2 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60907874; called by muse, mutect2, varscan2
- AMPD2 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56646210, COSV56646736; called by muse, mutect2, varscan2
- ARHGAP5 | c.1213_1216del p.L405Afs*3 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | catalogued as COSV61534321; called by mutect2, pindel, varscan2
- ARHGAP9 | c.1724G>A p.G575D (on ENST00000393797 / NM_001319850.2; = p.G556D on NM_032496.4) | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57359070; called by muse, mutect2, varscan2
- ARHGEF28 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV55249910; called by muse, mutect2, varscan2
- ARHGEF28 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs781655077, COSV55249928; called by muse, mutect2, varscan2
- ARHGEF3 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56324303; called by muse, mutect2, varscan2
- ATAD5 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1294728867, COSV58972616; called by muse, mutect2, varscan2
- ATP13A3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55462212; called by muse, mutect2, varscan2
- ATP2B4 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV58175251; called by muse, mutect2, varscan2
- ATP7B | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374592960; called by muse, mutect2, varscan2
- BCL7A | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55847041; called by muse, mutect2, varscan2
- BCL9L | c.1793T>G p.F598C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52682767, COSV52684044; called by muse, mutect2, varscan2
- BTBD2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99724531; called by muse, mutect2, varscan2
- C16orf86 | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54750932; called by muse, mutect2, varscan2
- C4orf51 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.035); catalogued as COSV71263883; called by muse, mutect2, varscan2
- C9orf64 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201215719, COSV59032236; called by muse, mutect2, varscan2
- CACNA1D | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.017); catalogued as COSV55440486; called by muse, mutect2, varscan2
- CANX | c.1730A>G p.D577G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV52983599; called by muse, mutect2, varscan2
- CASP8AP2 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52745680, COSV52750022; called by muse, mutect2, varscan2
- CBX6 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53320443; called by muse, mutect2, varscan2
- CCDC3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66558825; called by muse, mutect2, varscan2
- CCDC7 | c.3494C>A p.T1165N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.327); catalogued as COSV56538699; called by muse, mutect2, varscan2
- CD101 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56716735; called by muse, mutect2, varscan2
- CDH17 | c.1835T>A p.I612N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50326245; called by muse, mutect2, varscan2
- CDHR2 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV56135752, COSV99991814; called by muse, mutect2
- CDS2 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV66895776; called by muse, mutect2, varscan2
- CEMIP2 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV65485950; called by muse, mutect2, varscan2
- CEP70 | c.805T>G p.S269A | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53874647; called by muse, mutect2, varscan2
- CFTR | c.2796C>A p.F932L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV50043232; called by muse, mutect2, varscan2
- CGAS | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1451941695, COSV64807891; called by muse, mutect2, varscan2
- CHD1 | c.4525-1G>C p.X1509_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV52338180; called by muse, mutect2, varscan2
- COL4A5 | c.4807A>G p.T1603A | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs747907297, COSV60357732, COSV60361744; called by muse, mutect2, varscan2
- CR1 | c.4798A>G p.I1600V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.976); catalogued as rs917368537, COSV65456608; called by muse, mutect2, varscan2
- CRYBG1 | c.3592G>A p.V1198I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs368637688; called by muse, mutect2, varscan2
- CRYBG3 | c.8480T>C p.I2827T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1313820267, COSV51710166; called by muse, mutect2, varscan2
- CTH | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.206); catalogued as COSV61007606; called by muse, mutect2, varscan2
- CXCL16 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV53411223, COSV99543371; called by muse, mutect2, varscan2
- DCTN2 | c.521C>T p.A174V (on ENST00000548249 / NM_001261413.2; = p.A179V on NM_006400.4) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV63073405; called by muse, mutect2, varscan2
- DIAPH3 | c.2365G>A p.V789M (on ENST00000400324 / NM_001042517.2; = p.V526M on NM_030932.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99932804; called by muse, mutect2
- DLL1 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64536943; called by muse, mutect2
- DMD | c.3699A>C p.Q1233H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV63740328; called by muse, mutect2, varscan2
- DNMT3A | c.2501C>A p.T834N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53042739, COSV53045816; called by muse, mutect2, varscan2
- DPP4 | c.1583T>A p.M528K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62105634; called by muse, mutect2, varscan2
- ESRP2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753751967, COSV52172333; called by muse, mutect2, varscan2
- ETFB | c.378C>T p.A126= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58535332; called by muse, mutect2
- FAM124A | c.724C>T p.R242* (on ENST00000322475 / NM_001242312.2; = p.R278* on NM_145019.4) | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV54476702, COSV54479003; called by muse, mutect2, varscan2
- FAM189B | c.921C>G p.H307Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.755); catalogued as COSV56944074; called by muse, mutect2, varscan2
- FLT4 | c.500T>A p.V167D | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56101378; called by muse, mutect2, varscan2
- FMO5 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1553917377, COSV54204968; called by muse, mutect2, varscan2
- FN1 | c.3877A>G p.I1293V | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as rs868222219, COSV60548283; called by muse, mutect2, varscan2
- FOSB | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs775259642, COSV62278445; called by muse, mutect2, varscan2
- FPR2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs267605624; called by muse, mutect2, varscan2
- GARNL3 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV100150252, COSV59224428; called by muse, mutect2, varscan2
- GIT2 | c.928G>A p.E310K (on ENST00000355312 / NM_057169.5; = p.E312K on NM_014776.5) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100189188, COSV58078712; called by muse, mutect2, varscan2
- GNAI2 | c.169C>G p.H57D | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56493015; called by muse, mutect2, varscan2
- GPD2 | c.739A>G p.M247V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60090867; called by muse, mutect2, varscan2
- GPR180 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100978991; called by muse, mutect2, varscan2
- HOGA1 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV53967666; called by muse, mutect2, varscan2
- HOXC13 | c.615C>G p.H205Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54498250; called by muse, mutect2, varscan2
- HSBP1 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101419141; called by muse, mutect2, varscan2
- HUWE1 | c.2440G>C p.D814H | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53337961, COSV53345647; called by muse, mutect2, varscan2
- IDO1 | c.51T>G p.I17M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99503172; called by muse, mutect2, varscan2
- IL31RA | c.51_57del p.C17* | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | catalogued as COSV51679993; called by mutect2, pindel, varscan2
- IL4R | c.2137T>C p.Y713H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50139134; called by muse, mutect2, varscan2
- INTS7 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV65343855; called by muse, mutect2, varscan2
- IQCB1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1345829649, COSV60435922; called by muse, mutect2, varscan2
- JPH4 | c.895C>G p.R299G | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1292765771, COSV62508343; called by muse, mutect2, varscan2
- KLF4 | c.206C>G p.T69S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as COSV65928724; called by muse, mutect2
- KLRC2 | c.12A>C p.Q4H | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV67899521; called by muse, mutect2
- KMT5C | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99726061; called by muse, mutect2, varscan2
- KRBA1 | c.2689G>T p.A897S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as COSV99752212; called by muse, mutect2
- LILRA2 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV52189303; called by muse, mutect2, varscan2
- LYST | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67704349; called by muse, mutect2, varscan2
- MAF | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100391645; called by muse, mutect2, varscan2
- MAGEL2 | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV58566273, COSV58566447; called by muse, mutect2
- MED12L | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV56371720; called by muse, mutect2, varscan2
- MEIG1 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336421982, COSV65542406; called by muse, mutect2, varscan2
- MFSD8 | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56550658; called by muse, mutect2, varscan2
- MPZL1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV63256108; called by muse, mutect2, varscan2
- MTUS1 | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV50551949; called by muse, mutect2, varscan2
- MVP | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62421575; called by muse, mutect2, varscan2
- MYH2 | c.1770C>A p.D590E | Missense Mutation (SNP) | VAF 84/109 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV55433417; called by muse, mutect2
- MYH2 | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 82/106 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55433427; called by muse, mutect2
- MYO3A | c.4704G>T p.Q1568H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV56320704, COSV56322856; called by muse, mutect2, varscan2
- MYSM1 | c.555A>C p.Q185H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV68977143; called by muse, mutect2, varscan2
- NAP1L5 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV52018318; called by muse, mutect2, varscan2
- NCOR2 | c.6266G>A p.G2089D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201214871, COSV100656879; called by muse, mutect2, varscan2
- NOL4 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52341643; called by muse, mutect2, varscan2
- NOMO1 | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV55057476; called by muse, mutect2
- NRAP | c.4619G>A p.R1540Q (on ENST00000359988 / NM_001322945.2; = p.R1505Q on NM_006175.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs753418445, COSV63489037; called by muse, mutect2, varscan2
- OMP | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1339491683, COSV53686132; called by muse, mutect2, varscan2
- OR13C3 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66165678; called by muse, mutect2, varscan2
- OVGP1 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1422866558, COSV63857817; called by muse, mutect2, varscan2
- PABPC4 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV65723067; called by muse, mutect2, varscan2
- PARP3 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV67168232; called by muse, mutect2, varscan2
- PCCA | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV66189257; called by muse, mutect2, varscan2
- PCDHB10 | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV53376334; called by muse, mutect2, varscan2
- PCDHB11 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV61310199; called by muse, mutect2, varscan2
- PCOLCE | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV53824492; called by muse, mutect2, varscan2
- PDCD1LG2 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV67204043; called by muse, mutect2, varscan2
- PHF3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV50314512; called by muse, mutect2, varscan2
- PIGT | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.102); catalogued as rs529038853, COSV54125432; called by muse, mutect2, varscan2
- PKDCC | c.1438G>T p.V480F | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV54306112; called by muse, mutect2, varscan2
- PKLR | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331269086, COSV100712922, COSV100712937, COSV61360636; called by muse, mutect2, varscan2
- PLCL1 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as rs201915547; called by mutect2, varscan2
- PLD5 | c.502C>T p.R168C (on ENST00000442594; = p.R106C on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs202027708, COSV59137103; called by mutect2, varscan2
- PNMA1 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV54093288; called by muse, mutect2, varscan2
- POLR3C | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV61936171; called by muse, mutect2, varscan2
- PPP6R1 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.18); catalogued as COSV69799405; called by muse, mutect2, varscan2
- PRAMEF2 | c.1166T>C p.M389T | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53573165; called by muse, mutect2, varscan2
- PRKAR2B | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55923150; called by muse, mutect2, varscan2
- PRMT6 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100791135; called by muse, mutect2, varscan2
- PSMA6 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV54836715; called by muse, mutect2, varscan2
- PSMD13 | c.932T>A p.V311E | Missense Mutation (SNP) | VAF 10/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61500528; called by muse, mutect2
- PSMD2 | c.2345A>G p.H782R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59529131; called by muse, mutect2, varscan2
- PSME4 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66363785; called by muse, mutect2
- PTF1A | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1290892099, COSV64734862, COSV64735203; called by muse, mutect2, varscan2
- PTPN23 | c.700_711del p.Q234_W237del | In Frame Del (DEL) | VAF 20/61 reads (33%) | catalogued as COSV55543134; called by mutect2, pindel, varscan2
- QRICH1 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV62614767; called by muse, mutect2, varscan2
- RAB3B | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV63228323; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62782119, COSV62782700; called by muse, mutect2, varscan2
- RAB5B | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV64364711; called by muse, mutect2, varscan2
- RAD23A | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV57119950; called by muse, mutect2, varscan2
- RALGAPB | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV53435524; called by muse, mutect2, varscan2
- RB1CC1 | c.2321G>A p.S774N | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as rs1225110404, COSV50243877; called by muse, mutect2, varscan2
- RPS2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs764971592, COSV99238694; called by muse, mutect2
- RSAD1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 168/192 reads (88%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV51955057; called by muse, mutect2, varscan2
- RSF1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs751215835, COSV57837366; called by muse, mutect2, varscan2
- SEC16A | c.3019A>G p.N1007D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51523164; called by muse, mutect2, varscan2
- SEC31A | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52342446; called by muse, mutect2, varscan2
- SEPTIN14 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66426617; called by muse, mutect2, varscan2
- SLC22A14 | c.59T>C p.L20S | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV56196834; called by muse, mutect2, varscan2
- SLC22A4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs11568503, CM074536; called by muse, varscan2
- SLC25A4 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV55668519; called by muse, mutect2, varscan2
- SLC30A9 | c.528A>G p.K176= | Splice Region (SNP) | VAF 17/102 reads (17%) | catalogued as rs770648488, COSV52554590; called by muse, mutect2, varscan2
- SLC35B4 | c.152A>C p.E51A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV65984421; called by mutect2, varscan2
- SLC46A2 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs369303765; called by muse, mutect2, varscan2
- SMARCAD1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62773296; called by muse, mutect2
- SMC1B | c.3328A>G p.N1110D | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV62528711; called by muse, mutect2, varscan2
- SOX6 | c.1385G>T p.S462I (on ENST00000528429 / NM_001145819.2; = p.S421I on NM_017508.3) | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as COSV57039852; called by muse, mutect2, varscan2
- SPAG4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV65330099; called by muse, mutect2, varscan2
- SQLE | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 116/204 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV56280156; called by muse, mutect2, varscan2
- STAG1 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52604028, COSV99364628; called by muse, mutect2, varscan2
- STX8 | c.186G>T p.L62F | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV60488448; called by muse, mutect2, varscan2
- TAS2R3 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV56091684; called by muse, mutect2, varscan2
- TCF19 | c.286T>A p.L96M | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52563110; called by muse, mutect2, varscan2
- TDRD1 | c.1659A>G p.S553= | Splice Region (SNP) | VAF 28/69 reads (41%) | catalogued as COSV52588612; called by muse, mutect2, varscan2
- TENM3 | c.6312T>G p.I2104M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV69301730; called by muse, mutect2, varscan2
- TENM4 | c.8302C>T p.R2768W | Missense Mutation (SNP) | VAF 152/384 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780556556, COSV53614837; called by muse, mutect2, varscan2
- TERF2IP | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV55613041; called by muse, mutect2, varscan2
- TMEM143 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.713); catalogued as COSV53155530; called by muse, mutect2, varscan2
- TMEM14B | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 65/85 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV65355828, COSV65356058; called by muse, mutect2, varscan2
- TMEM63C | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.762); catalogued as COSV53601925; called by muse, mutect2, varscan2
- TPR | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV66599995; called by muse, mutect2, varscan2
- TROAP | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV57743363; called by muse, mutect2, varscan2
- TTC12 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100132860; called by muse, mutect2, varscan2
- TTN | c.80066G>A p.R26689K (on ENST00000591111; = p.R19265K on NM_003319.4) | Missense Mutation (SNP) | VAF 49/112 reads (44%) | PolyPhen benign (0); catalogued as COSV59932845; called by muse, mutect2, varscan2
- UBN1 | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs1485515104, COSV52166435; called by muse, mutect2, varscan2
- USP19 | c.1461A>C p.E487D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60045260; called by muse, mutect2, varscan2
- USP24 | c.6463C>A p.H2155N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.838); catalogued as COSV53763413; called by muse, mutect2, varscan2
- WDR37 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs769578695, COSV54127485; called by muse, mutect2, varscan2
- ZBTB38 | c.2345C>G p.S782* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100375331; called by muse, mutect2, varscan2
- ZDHHC3 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56100889; called by muse, mutect2, varscan2
- ZFP36L1 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.057); catalogued as COSV60544681; called by muse, mutect2, varscan2
- ZNF33B | c.2159C>G p.S720C | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV63942071; called by muse, mutect2, varscan2
- ZNF432 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV55415666; called by muse, mutect2, varscan2
- ZNF473 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1031592392, COSV54522325; called by muse, mutect2, varscan2
- ZNF750 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 110/125 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53958918; called by muse, mutect2, varscan2
- ZNF813 | c.1623T>A p.H541Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67175970; called by muse, mutect2, varscan2
- ZSCAN5A | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768324013, COSV99569750; called by muse, mutect2, varscan2
- ACP3 | c.968+8_968+15del p.X323_splice | Splice Site (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- CDC42 | c.149del p.P50Hfs*21 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- CDKN1A | c.194_207delinsA p.W65* | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by pindel, varscan2*
- DCAF5 | c.1373_1376delinsG p.D458_S459delinsG | In Frame Del (DEL) | VAF 24/55 reads (44%) | called by pindel, varscan2*
- EEF1A1 | c.753_761del p.Q251_Y254delinsH | In Frame Del (DEL) | VAF 29/92 reads (32%) | called by mutect2, pindel, varscan2
- FOXA1 | c.638_648del p.R213Lfs*10 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- FREM2 | c.7062_7063dup p.K2355Rfs*7 | Frame Shift Ins (INS) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- LYZL6 | c.269C>G p.S90W | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP3K5 | c.3502_3510delinsT p.T1168Cfs*13 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by pindel, varscan2*
- PTK2 | c.3015_3041del p.Q1006_Q1014del | In Frame Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel
- STAT6 | c.1349_1351del p.K450del | In Frame Del (DEL) | VAF 22/80 reads (28%) | called by pindel, varscan2
- TRHDE | c.1094_1102dup p.S365_D367dup | In Frame Ins (INS) | VAF 30/60 reads (50%) | called by mutect2, varscan2
- ABCC8 | c.3939C>A p.R1313= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV56847423; called by muse, mutect2, varscan2
- ABHD11 | c.771C>T p.L257= | Silent (SNP) | VAF 109/239 reads (46%) | catalogued as rs1554622022, COSV56105425; called by muse, mutect2, varscan2
- ALKBH5 | c.549C>T p.P183= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV52753364; called by muse, mutect2, varscan2
- ANKRD26 | c.1404C>T p.N468= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV65793287; called by muse, mutect2, varscan2
- BNC1 | c.1317G>A p.K439= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs996599294, COSV61756790; called by muse, mutect2, varscan2
- BRAF | c.678G>C p.V226= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV56102976; called by muse, mutect2, varscan2
- C22orf31 | c.624C>A p.L208= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV53310249; called by muse, mutect2, varscan2
- CAPN1 | c.231C>A p.S77= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54197168; called by muse, mutect2, varscan2
- CCDC7 | c.3495C>A p.T1165= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV56538712; called by muse, mutect2, varscan2
- CDH10 | c.369C>G p.A123= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV52573608; called by muse, mutect2, varscan2
- CDK11A | c.1188C>T p.P396= (on ENST00000378633 / NM_001313896.2; = p.P393= on NM_024011.4) | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs780290960, COSV62264768, COSV62266746; called by muse, mutect2, varscan2
- CLCNKB | c.336G>A p.Q112= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV65159944; called by muse, mutect2, varscan2
- COL4A5 | c.2379G>A p.G793= | Silent (SNP) | VAF 71/80 reads (89%) | catalogued as rs187572381, COSV60357712; called by muse, mutect2, varscan2
- EIF2B2 | c.441A>C p.T147= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV56719924; called by muse, mutect2, varscan2
- G6PD | c.1443C>G p.P481= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV63702489; called by muse, mutect2
- GCLC | c.612C>T p.V204= (on ENST00000643939; = p.V202= on NM_001498.4) | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV57594017; called by muse, mutect2, varscan2
- GPAT2 | c.1539G>A p.R513= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as rs1274875354, COSV64003209; called by muse, mutect2, varscan2
- GRB2 | c.555C>T p.V185= | Silent (SNP) | VAF 19/305 reads (6%) | catalogued as rs1433182449, COSV57303717; called by muse, mutect2
- HOOK3 | c.1347G>A p.E449= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV56880031; called by muse, mutect2, varscan2
- HOXB6 | c.588C>T p.N196= | Silent (SNP) | VAF 14/374 reads (4%) | catalogued as rs1394650708, COSV53312298; called by muse, mutect2
- ISM2 | c.577C>T p.L193= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as COSV53634242; called by muse, mutect2, varscan2
- ITGB2 | c.630G>A p.L210= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV56608535; called by muse, mutect2, varscan2
- ITPKC | c.1035A>T p.G345= | Silent (SNP) | VAF 76/171 reads (44%) | catalogued as COSV54573670; called by muse, mutect2, varscan2
- KCNMA1 | c.1839G>C p.L613= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54234011; called by muse, mutect2, varscan2
- KDM6A | c.1725C>T p.G575= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV65037993; called by muse, mutect2, varscan2
- KIAA1109 | c.1491C>T p.F497= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV52665207, COSV99164397; called by muse, mutect2, varscan2
- KLHL34 | c.48C>A p.L16= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV65278879; called by muse, mutect2, varscan2
- LRCH4 | c.258G>A p.A86= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs756507151, COSV53824486; called by muse, mutect2, varscan2
- LRRC66 | c.1422T>C p.T474= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV58632480; called by muse, mutect2, varscan2
- MAP3K6 | c.3288C>T p.I1096= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV58870656; called by muse, mutect2, varscan2
- MAP6 | c.1098A>G p.E366= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV59074684; called by muse, mutect2, varscan2
- MGRN1 | c.603C>T p.I201= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV52149159; called by muse, mutect2, varscan2
- MLKL | c.237C>T p.F79= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as rs1171664635, COSV58204408; called by muse, mutect2, varscan2
- NCAPD3 | c.888C>T p.I296= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV73257990; called by muse, mutect2, varscan2
- NLRC5 | c.5478C>T p.I1826= | Silent (SNP) | VAF 65/196 reads (33%) | catalogued as COSV52650737; called by muse, mutect2, varscan2
- NPY5R | c.882A>G p.A294= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV58451293; called by muse, mutect2, varscan2
- PADI3 | c.666G>A p.V222= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as rs755266036, COSV64934128; called by muse, mutect2, varscan2
- PAXBP1 | c.465A>C p.S155= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV51607402; called by muse, mutect2, varscan2
- PM20D2 | c.93C>T p.I31= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99248190; called by muse, varscan2
- POM121 | c.2424C>T p.F808= (on ENST00000434423; = p.F543= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- PPP1R10 | c.24C>G p.P8= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs1210999179, COSV64738677; called by muse, mutect2, varscan2
- RERE | c.804C>T p.Y268= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV61938416; called by muse, mutect2, varscan2
- RPRD2 | c.3291G>A p.R1097= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV64818992; called by muse, mutect2, varscan2
- SCNN1A | c.318C>T p.F106= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs148261445, COSV57434421; called by muse, mutect2, varscan2
- SHE | c.678C>T p.D226= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs745452697, COSV59071083; called by muse, mutect2, varscan2
- SLC28A1 | c.1224G>A p.Q408= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs760377456, COSV54477285; called by muse, mutect2, varscan2
- SLC36A1 | c.1251G>A p.P417= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs767431521, COSV54652617, COSV54655841; called by muse, mutect2, varscan2
- SORBS2 | c.72C>G p.V24= (on ENST00000284776 / NM_021069.5; = p.V70= on NM_003603.6) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV52993901; called by muse, mutect2, varscan2
- STPG1 | c.393C>A p.S131= (on ENST00000337248 / NM_001199013.2; = p.S84= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV50218066; called by muse, mutect2, varscan2
- TMBIM6 | c.474C>A p.S158= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV57278871; called by muse, mutect2, varscan2
- TMEM30A | c.516A>T p.G172= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV57874776; called by muse, mutect2, varscan2
- TSPAN3 | c.462A>C p.S154= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99144413; called by muse, mutect2, varscan2
- UNC13A | c.4326C>T p.L1442= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV53190510, COSV99409979; called by muse, mutect2, varscan2
- VCX3A | c.531G>A p.E177= | Silent (SNP) | VAF 90/290 reads (31%) | catalogued as rs140689741, COSV66910400, COSV66910607; called by muse, mutect2, varscan2
- WDR59 | c.811T>C p.L271= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV50933768; called by muse, mutect2, varscan2
- WNT10B | c.187C>T p.L63= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99975735; called by muse, mutect2
- ZMPSTE24 | c.606G>A p.L202= | Silent (SNP) | VAF 61/182 reads (34%) | catalogued as rs1447968022, COSV65638832; called by muse, mutect2, varscan2
- ZNF319 | c.393C>T p.P131= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV54621389; called by muse, mutect2
- AP000769.5 | chr11:65498890 A>G | 5'Flank (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1133+120T>G | Intron (SNP) | VAF 21/58 reads (36%) | catalogued as rs751897738, COSV59245173; called by muse, mutect2, varscan2
- CCDC6 | c.*277T>G | 3'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99569159; called by muse, mutect2, varscan2
- MACF1 | c.15832-10622C>T | Intron (SNP) | VAF 29/68 reads (43%) | catalogued as COSV57110703; called by muse, mutect2, varscan2
- RPL13A | c.342+76_343-58del | Intron (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- TREML2 | c.-16C>T | 5'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as rs769905357, COSV101530140; called by muse, mutect2, varscan2
- ZNF208 | c.*458A>C | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- ZNF665 | c.-3A>C | 5'UTR (SNP) | VAF 140/326 reads (43%) | catalogued as COSV67213983; called by muse, mutect2, varscan2
